Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5767, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5767-01A (Primary Tumor).

Diagnosis

1. Predominantly poorly differentiated adenocarcinoma of the prostate on both sides with predominance in the anterior and right rectolateral peripheral zone. Maximum tumor spread 0.9 cm. Focally perineural tumor invasion. No extraprostatic tumor growth and no identifiable invasion of the vessels. Tumor-free seminal vesicles and tumor-free resection margins. Remaining prostate tissue with myoglandular hyperplasia in the transitional zone. Tumor and dysplasia-free prostatic urethra.
2. Fatty tissue with a microscopic, tumor-free lymph node.
3. Three tumor-free lymph nodes.
4. Five tumor-free lymph nodes.
5. Two tumor-free lymph nodes.
6. Fatty tissue with a tumor-free, microscopic lymph node.
7. Fatty tissue with five tumor-free lymph nodes.

Remark

In summary, the tumor is classified as follows:

pT2c, pN0 (0/19), L0, V0; Gleason 4+3 = 7 (approx. 60% Gleason 4); complete local resection.

Source: NCI Genomic Data Commons file 87523085-24e5-4173-ad03-4e667d4abb64 (TCGA-CH-5767.237374E0-5B18-407C-AE42-898A95C14FA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).